Somatic mutation profile of tumor specimen TCGA-D1-A2G7-01A (aliquot TCGA-D1-A2G7-01A-21D-A17W-09) from TCGA case TCGA-D1-A2G7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.5 years (23,913 days).
Specimen TCGA-D1-A2G7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) debe78f2-ef1e-42eb-bbd1-d75d6d76b706.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A2G7-10A (Blood Derived Normal), aliquot TCGA-D1-A2G7-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab6f3ab9-2943-4a1d-bb3a-c726074d09ea

The open-access MAF lists 51 somatic variants for this specimen: 33 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 16, Nonsense Mutation 3, Splice Site 1, Frame Shift Ins 1, 5'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1678G>T p.D560Y (on ENST00000521381 / NM_181523.3; = p.D290Y on NM_181504.4) | Missense Mutation (SNP) | VAF 20/32 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519839, COSV57123942, COSV57127598, COSV57130158; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 13/20 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSBG2 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as rs142290585, COSV53124454; called by muse, mutect2, varscan2
- AVPR2 | c.672C>A p.C224* | Nonsense Mutation (SNP) | VAF 7/130 reads (5%) | catalogued as COSV100509424, COSV61685881; called by muse, mutect2
- DAPP1 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99596615; called by muse, mutect2, varscan2
- DHX29 | c.589G>C p.A197P | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99286996; called by muse, mutect2, varscan2
- DNAI4 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 33/76 reads (43%) | catalogued as COSV100925200; called by muse, mutect2, varscan2
- DSG4 | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV100355387; called by muse, mutect2, varscan2
- ESPNL | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1397304358, COSV100547619; called by muse, mutect2, varscan2
- GPR158 | c.1767C>A p.F589L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV100892912; called by muse, mutect2, varscan2
- HELZ2 | c.2873G>T p.R958I (on ENST00000467148 / NM_001037335.2; = p.R389I on NM_033405.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.218); catalogued as COSV100915446; called by muse, mutect2
- HMGB2 | c.555C>G p.N185K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs766247171, COSV56633321; called by muse, mutect2, varscan2
- IGBP1 | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100642895; called by muse, mutect2, varscan2
- IRS4 | c.3638C>T p.P1213L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.289); catalogued as COSV64534681; called by muse, mutect2, varscan2
- KCNK13 | c.911G>C p.R304T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as COSV99965517; called by muse, mutect2, varscan2
- LZTR1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs747430075, COSV53147792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAGEA1 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV100756612; called by muse, mutect2, varscan2
- NPL | c.230+1G>A p.X77_splice | Splice Site (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99277259; called by muse, mutect2, varscan2
- OR4K15 | c.248T>A p.M83K (on ENST00000305051; = p.M59K on NM_001005486.1) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100520979, COSV59303572; called by muse, mutect2, varscan2
- OSBPL3 | c.434G>C p.R145T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100513729; called by muse, mutect2, varscan2
- PIGT | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99648693; called by muse, mutect2, varscan2
- PPRC1 | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99531329; called by muse, mutect2, varscan2
- RALGAPB | c.2428G>A p.V810M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as COSV99484766; called by muse, mutect2, varscan2
- SACS | c.7169G>C p.G2390A | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101207202; called by muse, mutect2, varscan2
- SMU1 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV101238500; called by muse, mutect2, varscan2
- SRCAP | c.2483G>T p.R828L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99349387; called by mutect2, varscan2
- TBC1D19 | c.894T>A p.D298E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99335984; called by muse, mutect2, varscan2
- TGFBRAP1 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99304752; called by muse, mutect2, varscan2
- UBE4A | c.2636C>G p.S879C (on ENST00000252108 / NM_001204077.2; = p.S886C on NM_004788.4) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs781806878, COSV99347892; called by muse, mutect2, varscan2
- VPS33B | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV100325448; called by muse, mutect2, varscan2
- WDFY3 | c.2855G>T p.C952F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV55694356, COSV99882227; called by muse, mutect2, varscan2
- RBKS | c.121_124dup p.I42Nfs*6 | Frame Shift Ins (INS) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- SLC18B1 | c.1288_1296del p.Y430_R432del | In Frame Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- ABCA5 | c.2565G>A p.L855= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV101201014; called by muse, mutect2
- ALK | c.4425C>T p.H1475= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs139039449, COSV66591681; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ARF6 | c.405C>A p.I135= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100028356; called by muse, mutect2, varscan2
- COG3 | c.72C>G p.L24= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100596386; called by muse, mutect2, varscan2
- CRYBG3 | c.7344A>G p.E2448= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV99476631; called by muse, mutect2, varscan2
- DPY19L3 | c.726G>C p.L242= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100639118; called by muse, mutect2, varscan2
- IGHV1-58 | c.213C>T p.V71= | Silent (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- LRP1B | c.2280C>A p.S760= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs1264096842, COSV67182972, COSV67276506; called by muse, mutect2, varscan2
- MATN2 | c.28C>T p.L10= | Silent (SNP) | VAF 42/77 reads (55%) | catalogued as COSV99645740; called by muse, mutect2, varscan2
- MFHAS1 | c.2781G>C p.V927= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99359228; called by muse, mutect2, varscan2
- MYO18B | c.7209G>A p.P2403= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs892361656, COSV100122729; called by muse, mutect2, varscan2
- PCDHB10 | c.1680C>T p.F560= | Silent (SNP) | VAF 82/134 reads (61%) | catalogued as rs781926154, COSV99503741; called by muse, mutect2, varscan2
- PIGT | c.1029G>A p.E343= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99648700; called by muse, mutect2, varscan2
- PRKG2 | c.1953T>G p.S651= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100019350; called by muse, mutect2, varscan2
- RELA | c.1065G>A p.L355= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs143229162; called by muse, mutect2, varscan2
- SPON1 | c.294C>G p.L98= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV100115299; called by muse, mutect2, varscan2
- SLC2A9 | chr4:10025954 T>A | 5'Flank (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99303956; called by muse, mutect2, varscan2
- TMEM99 | n.585G>A | RNA (SNP) | VAF 14/35 reads (40%) | catalogued as rs752360948, COSV56982063; called by muse, mutect2, varscan2
